Somatic mutation profile of tumor specimen TCGA-FD-A3B5-01A (aliquot TCGA-FD-A3B5-01A-11D-A20D-08) from TCGA case TCGA-FD-A3B5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 86.1 years (31,442 days).
Specimen TCGA-FD-A3B5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 114ca8c7-4da8-4481-bac0-da84889db4b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3B5-10A (Blood Derived Normal), aliquot TCGA-FD-A3B5-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed48a87b-8050-424c-a399-e674306060f6

The open-access MAF lists 156 somatic variants for this specimen: 125 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 29, Nonsense Mutation 13, Splice Site 3, Intron 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSS3 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 66/85 reads (78%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV54086603; called by muse, mutect2, varscan2
- ATM | c.6573-1G>A p.X2191_splice | Splice Site (SNP) | VAF 50/67 reads (75%) | catalogued as COSV53731103; called by muse, mutect2, varscan2
- ATP2B1 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 69/99 reads (70%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV53804893; called by muse, mutect2, varscan2
- ATP2C2 | c.2708A>G p.N903S | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV52293547; called by muse, mutect2, varscan2
- ATP6V1A | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56361303; called by muse, mutect2, varscan2
- BDP1 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.303); catalogued as rs374517452; called by muse, mutect2, varscan2
- C11orf65 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67596970; called by muse, mutect2, varscan2
- C16orf71 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1247708025, COSV73918477; called by muse, mutect2, varscan2
- C1orf43 | c.578G>A p.R193Q (on ENST00000368521 / NM_001297718.2; = p.R159Q on NM_015449.4) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1016886052, COSV62965968; called by muse, mutect2, varscan2
- CACNG3 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV50063828, COSV99136896; called by muse, mutect2, varscan2
- CAPN3 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 141/296 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as rs1466584885, COSV55514400; called by muse, mutect2, varscan2
- CDHR5 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57641765; called by muse, mutect2, varscan2
- CEACAM5 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs376701458; called by muse, mutect2
- CELF2 | c.576G>A p.M192I (on ENST00000416382 / NM_001025077.3; = p.M199I on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59970658; called by muse, mutect2, varscan2
- CEP350 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100658334, COSV62485699; called by muse, mutect2, varscan2
- CHUK | c.1129-1G>A p.X377_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as COSV64917373, COSV64918201; called by muse, mutect2
- CIAO1 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1362259669, COSV51497207; called by muse, mutect2
- CLGN | c.411G>C p.L137F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV57773566, COSV57776543; called by mutect2, varscan2
- COL11A1 | c.2864G>A p.G955E | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62175422; called by muse, mutect2, varscan2
- CSMD1 | c.1918G>A p.A640T (on ENST00000520002; = p.A639T on NM_033225.6) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as rs779494957, COSV59292435; called by muse, mutect2, varscan2
- DAGLB | c.1613G>C p.G538A | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV51702805; called by muse, mutect2, varscan2
- DCLK2 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56200709; called by muse, mutect2, varscan2
- DENND1C | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as COSV67372248; called by muse, mutect2, varscan2
- DNAH11 | c.12511G>A p.E4171K | Missense Mutation (SNP) | VAF 139/387 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV60944154; called by muse, mutect2, varscan2
- DNAJB11 | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777074056, COSV54002028; called by muse, mutect2, varscan2
- DOCK2 | c.4487A>T p.E1496V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56946259; called by muse, mutect2, varscan2
- EMILIN2 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV54420409, COSV54421799; called by muse, mutect2, varscan2
- EPHB6 | c.2545G>C p.G849R | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844466, COSV63890870; called by muse, mutect2, varscan2
- EVC2 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs763041096, COSV60388858; called by muse, mutect2, varscan2
- EXOSC4 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as COSV60155389; called by muse, mutect2, varscan2
- FAM209B | c.5G>T p.W2L | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as COSV64915080; called by muse, mutect2, varscan2
- FBXO22 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.723); catalogued as COSV100380724, COSV57616882; called by muse, mutect2, varscan2
- FGFR2 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs372348666, COSV60655200; called by muse, mutect2, varscan2
- FOXE3 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV58632533; called by muse, mutect2, varscan2
- GABRA4 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51923863; called by muse, mutect2, varscan2
- GEN1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV58055588; called by muse, mutect2, varscan2
- GNAO1 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52611534; called by muse, mutect2
- HSD17B4 | c.589C>G p.L197V (on ENST00000414835 / NM_001199291.3; = p.L172V on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV56334112; called by muse, mutect2, varscan2
- IFI16 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as rs1296950047, COSV55534685; called by muse, varscan2
- IRX5 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as COSV58058536; called by muse, mutect2, varscan2
- KCNH6 | c.1080C>G p.I360M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV59001321; called by muse, mutect2, varscan2
- KDM5A | c.2716G>T p.E906* | Nonsense Mutation (SNP) | VAF 16/194 reads (8%) | catalogued as COSV66992583; called by muse, mutect2
- KDM6A | c.3634C>T p.Q1212* | Nonsense Mutation (SNP) | VAF 33/39 reads (85%) | catalogued as COSV65037414; called by muse, mutect2, varscan2
- KIF11 | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53269196; called by muse, mutect2, varscan2
- KIF21A | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62766979; called by muse, mutect2, varscan2
- KLHL17 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV58531078; called by muse, mutect2, varscan2
- KMT2C | c.5272C>T p.R1758C | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51386703; called by muse, mutect2, varscan2
- LILRB2 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV58743913, COSV58744747, COSV58745313; called by muse, mutect2, varscan2
- LRRC31 | c.1421G>T p.C474F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV52979902; called by muse, mutect2, varscan2
- MACO1 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV65475303, COSV65475397; called by muse, mutect2, varscan2
- MAGI1 | c.2654A>G p.K885R (on ENST00000402939 / NM_001033057.2; = p.K913R on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.279); catalogued as rs1204814123, COSV58317518; called by muse, mutect2, varscan2
- MANEAL | c.1362G>T p.Q454H (on ENST00000373045 / NM_001113482.1; = p.Q232H on NM_152496.2) | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100203910, COSV61115675; called by muse, varscan2
- MARCHF11 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 156/337 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60126749; called by muse, mutect2, varscan2
- MDN1 | c.11203T>C p.S3735P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV65518386; called by muse, mutect2, varscan2
- MFSD14A | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64514418; called by muse, mutect2, varscan2
- MIEN1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54065114; called by muse, mutect2, varscan2
- MIS18BP1 | c.3358G>A p.E1120K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57498136; called by muse, mutect2, varscan2
- MRPL21 | c.423C>A p.F141L | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62913197; called by muse, mutect2, varscan2
- MTF2 | c.1517G>C p.R506T | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as COSV100940125, COSV64769759; called by muse, mutect2, varscan2
- MUC17 | c.8404A>G p.T2802A | Missense Mutation (SNP) | VAF 120/536 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.636); catalogued as rs1275104340, COSV60282228; called by muse, mutect2, varscan2
- NAA35 | c.993A>T p.R331S | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV64484172; called by muse, mutect2, varscan2
- NAP1L1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as COSV53873720; called by muse, mutect2, varscan2
- NCAM2 | c.2098G>T p.G700W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV53061102; called by muse, varscan2
- NCKAP1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV62940151; called by muse, mutect2, varscan2
- NEPRO | c.1529G>C p.G510A | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV55606023; called by muse, mutect2, varscan2
- NLRP10 | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as rs1321788996, COSV60779037; called by muse, mutect2, varscan2
- NLRP10 | c.1509G>C p.E503D | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV60779046; called by muse, mutect2, varscan2
- NOL12 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.346); catalogued as rs756287059, COSV63030762; called by muse, mutect2, varscan2
- NPC1L1 | c.2298G>A p.M766I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56923106; called by muse, mutect2
- NRG3 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64545820, COSV64548799; called by muse, mutect2, varscan2
- P2RY2 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs766632202, COSV60775524; called by muse, mutect2, varscan2
- PCDH8 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1047810990, COSV58811189; called by muse, varscan2
- PHLDB2 | c.3117G>C p.E1039D (on ENST00000393925 / NM_001134439.2; = p.E996D on NM_145753.2) | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67308910; called by muse, mutect2, varscan2
- PKD1 | c.11252A>T p.Q3751L (on ENST00000262304 / NM_001009944.3; = p.Q3750L on NM_000296.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as CM034122, COSV51912054; called by muse, mutect2, varscan2
- PLA1A | c.300G>C p.W100C | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415723063, COSV56330763; called by muse, mutect2, varscan2
- POU2F1 | c.1039G>C p.E347Q (on ENST00000541643 / NM_001365848.1; = p.E370Q on NM_002697.4) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV54813745; called by muse, mutect2, varscan2
- PREPL | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV53215453, COSV53219978; called by muse, mutect2, varscan2
- PREX2 | c.3419C>G p.S1140* | Nonsense Mutation (SNP) | VAF 50/104 reads (48%) | catalogued as COSV55770879; called by muse, mutect2, varscan2
- PRRC1 | c.1044_1047del p.C348Wfs*12 | Frame Shift Del (DEL) | VAF 35/87 reads (40%) | catalogued as rs1406712333; called by mutect2, pindel, varscan2
- PRRX1 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.227); catalogued as rs1218432646, COSV53411685, COSV53413919; called by muse, varscan2
- PRRX1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.581); catalogued as COSV53411702; called by muse, varscan2
- PSPH | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV51909346; called by muse, mutect2, varscan2
- PSRC1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs144416204; called by muse, mutect2, varscan2
- RABEP2 | c.195G>C p.E65D | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62868732; called by muse, mutect2
- RABGEF1 | c.1228G>A p.E410K (on ENST00000439720 / NM_001287061.2; = p.E397K on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV53161156; called by muse, varscan2
- RABGEF1 | c.1303G>C p.E435Q (on ENST00000439720 / NM_001287061.2; = p.E422Q on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as COSV53161174; called by muse, varscan2
- RBM26 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1315057398, COSV57392189; called by muse, mutect2, varscan2
- RGS5 | c.161C>G p.S54W | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100009184, COSV58351693; called by muse, mutect2, varscan2
- RPAP1 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764215280, COSV58537425; called by muse, mutect2, varscan2
- RXRA | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.124); catalogued as COSV62683693; called by muse, mutect2, varscan2
- SERINC3 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54855724; called by muse, mutect2, varscan2
- SPECC1L | c.2070C>G p.I690M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58656972; called by muse, mutect2, varscan2
- SRSF2 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); catalogued as COSV57970563; called by muse, mutect2, varscan2
- STAG2 | c.2182C>T p.Q728* | Nonsense Mutation (SNP) | VAF 66/86 reads (77%) | catalogued as COSV99493750; called by muse, mutect2, varscan2
- STAG3 | c.2011G>T p.V671L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV57928158; called by muse, mutect2, varscan2
- STK36 | c.1353G>C p.Q451H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV55324790; called by muse, mutect2, varscan2
- SYNE2 | c.2538C>G p.I846M | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV59942165; called by muse, mutect2
- TBC1D1 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs751773027, COSV54715337; called by muse, mutect2, varscan2
- TFE3 | c.763T>G p.S255A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV59946149; called by muse, mutect2, varscan2
- TULP4 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV65573077; called by muse, mutect2, varscan2
- UBR5 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV55279851; called by muse, mutect2
- UHRF1BP1 | c.1801G>C p.E601Q | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV51953288; called by muse, mutect2, varscan2
- USP13 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55863313, COSV55865574; called by muse, mutect2, varscan2
- VPS11 | c.490G>A p.V164M (on ENST00000620429; = p.V708M on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs368691793; called by muse, mutect2, varscan2
- VSIG4 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV66073385; called by muse, mutect2, varscan2
- WNK3 | c.1485A>C p.R495S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63612447; called by muse, mutect2, varscan2
- ZNF287 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67688181; called by muse, mutect2, varscan2
- ZNF334 | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61618079; called by muse, mutect2, varscan2
- ZNF432 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV55415619; called by muse, mutect2, varscan2
- ZNF470 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1209152973, COSV57967877; called by muse, mutect2, varscan2
- ZNF655 | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV53158221; called by muse, mutect2, varscan2
- ZNF765 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67182144; called by muse, mutect2, varscan2
- C18orf25 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- CEP170B | c.843G>C p.K281N (on ENST00000453495; = p.K210N on NM_015005.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- DCLRE1A | c.2863C>T p.Q955* | Nonsense Mutation (SNP) | VAF 42/127 reads (33%) | called by muse, mutect2, varscan2
- IL27RA | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.357); called by muse, mutect2
- MOV10L1 | c.1209dup p.L404Afs*15 | Frame Shift Ins (INS) | VAF 63/165 reads (38%) | called by mutect2, pindel, varscan2
- PIDD1 | c.975-5_975-2del p.X325_splice | Splice Site (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2
- ROR1 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 101/189 reads (53%) | called by muse, mutect2, varscan2
- SLC26A11 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- TEX14 | c.3490G>T p.E1164* (on ENST00000240361 / NM_001201457.2; = p.E1118* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- TMEM132A | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 19/240 reads (8%) | called by muse, mutect2
- ZNF501 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- ZNF827 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- A1CF | c.1509G>A p.L503= (on ENST00000373993 / NM_138932.2; = p.L495= on NM_014576.4) | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV50958320; called by muse, mutect2, varscan2
- ADAP1 | c.1020G>A p.T340= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as rs146090079; called by muse, mutect2, varscan2
- AGPS | c.1344A>G p.K448= | Silent (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1581G>A p.L527= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV61708154; called by muse, mutect2, varscan2
- ARSH | c.189G>C p.L63= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- B3GNT6 | c.1062A>G p.L354= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1199913705; called by muse, mutect2
- CAPN7 | c.1854T>G p.V618= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV53777167; called by muse, mutect2, varscan2
- CHMP7 | c.558C>T p.L186= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs759170647, COSV57532165; called by muse, mutect2, varscan2
- CHRNG | c.1173C>G p.L391= | Silent (SNP) | VAF 60/88 reads (68%) | catalogued as COSV67315311; called by muse, mutect2, varscan2
- CLIP1 | c.4056G>C p.L1352= (on ENST00000620786 / NM_001247997.1; = p.L1341= on NM_002956.2) | Silent (SNP) | VAF 139/307 reads (45%) | catalogued as COSV56798637; called by muse, mutect2, varscan2
- FOXM1 | c.1185G>A p.V395= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as COSV61205439; called by muse, mutect2, varscan2
- IFI27 | c.174G>A p.A58= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs376868044; called by muse, varscan2
- INPP5B | c.2562A>T p.P854= (on ENST00000373023; = p.P774= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as COSV65959674; called by muse, mutect2, varscan2
- INTS5 | c.1515G>A p.L505= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV57950554; called by muse, mutect2, varscan2
- NR3C2 | c.2463T>C p.H821= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV60986573; called by muse, mutect2
- PCDHA7 | c.327C>T p.I109= | Silent (SNP) | VAF 33/270 reads (12%) | catalogued as rs1554134455, COSV65342449, COSV65344397; called by muse, mutect2, varscan2
- PKD1L1 | c.5166C>T p.L1722= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as rs140257069, COSV56959721; called by muse, mutect2, varscan2
- POGK | c.765G>A p.K255= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as COSV63311339; called by muse, mutect2, varscan2
- PPP2R2A | c.1315C>T p.L439= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV60096050; called by muse, mutect2, varscan2
- PRR12 | c.1305G>A p.S435= (on ENST00000615927; = p.S1256= on NM_020719.3) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV69816771; called by muse, mutect2, varscan2
- SLC34A1 | c.93C>T p.Y31= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs144202147; called by muse, varscan2
- SOCS4 | c.232T>C p.L78= | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as COSV59460063; called by muse, mutect2, varscan2
- TGM5 | c.78C>T p.I26= | Silent (SNP) | VAF 81/161 reads (50%) | catalogued as COSV55008951; called by muse, mutect2, varscan2
- TMEM44 | c.1413G>C p.L471= (on ENST00000392432 / NM_001166305.2; = p.L434= on NM_138399.5) | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as COSV56447452, COSV56447768; called by muse, mutect2, varscan2
- TUBG2 | c.576C>G p.L192= | Silent (SNP) | VAF 100/226 reads (44%) | catalogued as COSV52216951; called by muse, mutect2, varscan2
- UBE2D4 | c.168T>C p.F56= | Silent (SNP) | VAF 73/178 reads (41%) | catalogued as COSV55972906; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2013G>A p.Q671= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as COSV51953296; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2382G>A p.L794= | Silent (SNP) | VAF 83/170 reads (49%) | catalogued as COSV51953309; called by muse, mutect2, varscan2
- VSIG2 | c.369C>A p.V123= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV52517984; called by muse, mutect2, varscan2
- NFASC | c.2471-1314C>T | Intron (SNP) | VAF 9/67 reads (13%) | catalogued as COSV58360628; called by muse, mutect2, varscan2
- RPS2 | c.709+106C>G | Intron (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99238841; called by muse, mutect2, varscan2
